Somatic mutation profile of tumor specimen HCM-CSHL-0158-C20-01A (aliquot HCM-CSHL-0158-C20-01A-21D-A77E-36) from HCMI case HCM-CSHL-0158-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.2 years (20,877 days).
Specimen HCM-CSHL-0158-C20-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 569c436c-ae0e-4900-bb22-728cb81d8acd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0158-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0158-C20-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00806148-d63b-457d-8908-bcbdd30543bc

The open-access MAF lists 107 somatic variants for this specimen: 79 protein-altering or splice-affecting, 19 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 19, Intron 7, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3880C>T p.Q1294* | Nonsense Mutation (SNP) | VAF 39/315 reads (12%) | hotspot (GDC flag); catalogued as rs1554085373, CD058148, CD132712, CM930027, COSV57323524; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 85/229 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 121/451 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1254014649; called by muse, mutect2, varscan2
- ABCA9 | c.2519C>T p.A840V | Missense Mutation (SNP) | VAF 73/308 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs547831027, COSV60619833; called by muse, mutect2, varscan2
- ADAMTS5 | c.2536C>T p.R846C | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371425346; called by muse, mutect2
- ADAMTS5 | c.1807G>A p.G603R | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865877973, COSV53182560, COSV99538047; called by muse, mutect2, varscan2
- ADCY6 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1312450652, COSV57166651; called by muse, mutect2, varscan2
- AHNAK2 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 64/330 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200854519; called by muse, mutect2, varscan2
- C11orf24 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs147283671; called by muse, mutect2, varscan2
- CCNYL1 | c.290C>T p.T97M (on ENST00000295414 / NM_001330218.2; = p.T27M on NM_152523.2) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.775); catalogued as rs542007393; called by muse, mutect2, varscan2
- CDH22 | c.1874G>A p.G625D | Missense Mutation (SNP) | VAF 34/343 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV64838474; called by muse, mutect2
- CDH6 | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 130/423 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs772276938; called by muse, mutect2, varscan2
- CDON | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 100/373 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs769676286, CM160061, COSV54997908; called by muse, mutect2, varscan2
- COL23A1 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs776511487; called by muse, mutect2, varscan2
- CROCC | c.3320G>A p.R1107Q | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.236); catalogued as rs761081353, COSV65015293; called by muse, mutect2, varscan2
- CSRNP3 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 132/440 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs374214581; called by muse, mutect2, varscan2
- DENND2A | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 120/262 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); catalogued as rs764039930, COSV52054933, COSV99327036; called by muse, mutect2, varscan2
- EID1 | c.560_561del p.E187Vfs*6 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs750781501; called by pindel, varscan2
- EIF2B5 | c.746G>A p.R249Q (on ENST00000647909; = p.R241Q on NM_003907.3) | Missense Mutation (SNP) | VAF 71/421 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV56606505; called by muse, mutect2, varscan2
- EYS | c.4805C>T p.A1602V | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.034); catalogued as rs1353073807; called by muse, mutect2, varscan2
- GPR132 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 70/332 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as rs573418373; called by muse, mutect2, varscan2
- IGSF9 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.806); catalogued as rs143847211; called by muse, mutect2, varscan2
- INAVA | c.67dup p.E23Gfs*11 | Frame Shift Ins (INS) | VAF 16/64 reads (25%) | catalogued as rs750421792; called by mutect2, pindel, varscan2
- ITGAD | c.2443G>A p.V815M | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs767511529, COSV66758313; called by muse, mutect2, varscan2
- KCNA5 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs1020769441, COSV99363713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM4B | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs143993914; called by muse, mutect2, varscan2
- KHDC1L | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.984); catalogued as rs369792369; called by mutect2, varscan2
- KIAA0513 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs1366593033, COSV50745281; called by muse, mutect2, varscan2
- KIF1A | c.1778G>T p.R593L | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57495082; called by muse, mutect2, varscan2
- KLHL32 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs752627797, COSV65111334; called by muse, mutect2, varscan2
- KLRD1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755827000, COSV60273399; called by muse, mutect2, varscan2
- LCE2B | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 100/378 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs759523297, COSV100909340, COSV64228104; called by muse, mutect2, varscan2
- LRP2 | c.3667+1G>A p.X1223_splice | Splice Site (SNP) | VAF 32/194 reads (16%) | catalogued as rs752197557, COSV55546404; called by muse, mutect2, varscan2
- MARCHF4 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1214830803, COSV56102656; called by muse, mutect2, varscan2
- MRPL47 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs201911825; called by muse, mutect2, varscan2
- MYLPF | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs1007034057, COSV58443575; called by muse, mutect2, varscan2
- NEFM | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV55334374; called by muse, mutect2, varscan2
- NMBR | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143952823, COSV104382245, COSV99237157; called by muse, mutect2, varscan2
- PCDHGB5 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 149/529 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775633916; called by muse, mutect2, varscan2
- PERM1 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 83/296 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1160965040, COSV100379051; called by muse, mutect2, varscan2
- PHKA2 | c.3389G>A p.R1130H | Missense Mutation (SNP) | VAF 115/222 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs758012915; called by muse, mutect2, varscan2
- PTPRN | c.2782C>T p.R928C | Missense Mutation (SNP) | VAF 81/255 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772936871, COSV55348561, COSV99834068; called by muse, mutect2, varscan2
- RYR2 | c.10415G>A p.R3472Q | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs1460432238, COSV63703137; called by muse, mutect2, varscan2
- SEMA6B | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as rs753670884; called by muse, mutect2, varscan2
- SERPINH1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 170/556 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs776140347; called by muse, mutect2, varscan2
- SH3BP5 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 63/499 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1289820212, COSV53743114; called by muse, mutect2, varscan2
- SLC16A7 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.358); catalogued as rs141650282; called by muse, mutect2, varscan2
- SPG7 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs376397768; called by muse, mutect2, varscan2
- SYN1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 89/170 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1171134481, COSV55980351; called by muse, mutect2, varscan2
- SYT7 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 31/316 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99801903; called by muse, mutect2
- TBC1D9 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757700003, COSV65932265; called by muse, mutect2, varscan2
- TIAM1 | c.3613G>A p.A1205T | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs529598323, COSV54543783; called by muse, mutect2, varscan2
- TRPM2 | c.3305C>T p.P1102L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.448); catalogued as rs777861519, COSV55966341; called by muse, mutect2, varscan2
- TTN | c.11360G>T p.S3787I (on ENST00000591111; = p.S3741I on NM_003319.4) | Missense Mutation (SNP) | VAF 39/157 reads (25%) | catalogued as COSV59950405; called by muse, mutect2, varscan2
- ULK2 | c.3080C>T p.S1027L | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs141459584; called by muse, mutect2, varscan2
- VWA1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs1280014527; called by muse, mutect2, varscan2
- WDR13 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.955); catalogued as COSV54332202; called by muse, mutect2, varscan2
- ABCD1 | c.2165A>G p.E722G | Missense Mutation (SNP) | VAF 72/116 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- APC | c.3081_3082del p.Y1027* | Frame Shift Del (DEL) | VAF 52/198 reads (26%) | called by pindel, varscan2
- BCL9 | c.3838C>T p.Q1280* | Nonsense Mutation (SNP) | VAF 41/243 reads (17%) | called by muse, mutect2, varscan2
- BRINP2 | c.2038del p.I680Lfs*21 | Frame Shift Del (DEL) | VAF 50/186 reads (27%) | called by mutect2, pindel, varscan2
- CENPO | c.594+2T>A p.X198_splice | Splice Site (SNP) | VAF 24/85 reads (28%) | called by muse, varscan2
- CLDN11 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 43/312 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- DHX40 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ELF3 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 140/464 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- F2 | c.1511G>T p.W504L | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXL19 | c.526T>G p.L176V | Missense Mutation (SNP) | VAF 95/434 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KCNQ4 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 59/387 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MPO | c.245A>C p.E82A | Missense Mutation (SNP) | VAF 141/532 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PCDHGB5 | c.220T>A p.Y74N | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PCNT | c.4368G>C p.Q1456H | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- PDPK1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- PXDN | c.3784C>A p.L1262M | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAG1 | c.2416G>T p.E806* | Nonsense Mutation (SNP) | VAF 92/384 reads (24%) | called by muse, mutect2, varscan2
- SETD6 | c.1343G>A p.S448N (on ENST00000219315 / NM_001160305.4; = p.S424N on NM_024860.3) | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SPATA31A6 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 27/478 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- STAB2 | c.5230C>A p.L1744I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TNRC6B | c.1823del p.L608* | Frame Shift Del (DEL) | VAF 32/154 reads (21%) | called by mutect2, pindel, varscan2
- WFDC9 | c.79A>G p.N27D | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- A4GALT | c.1041G>A p.E347= | Silent (SNP) | VAF 45/164 reads (27%) | catalogued as rs761140271; called by muse, mutect2, varscan2
- AHNAK2 | c.2187C>T p.S729= | Silent (SNP) | VAF 140/471 reads (30%) | catalogued as rs568401227, COSV60912601; called by muse, mutect2, varscan2
- ASRGL1 | c.744G>A p.A248= | Silent (SNP) | VAF 107/345 reads (31%) | catalogued as rs374349770; called by muse, mutect2, varscan2
- COL20A1 | c.87C>T p.S29= | Silent (SNP) | VAF 58/274 reads (21%) | catalogued as rs761610149; called by muse, mutect2, varscan2
- DGKB | c.1356A>G p.G452= | Silent (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- DLG2 | c.1641C>T p.Y547= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs183726641, COSV54646141; called by muse, mutect2, varscan2
- EPHA8 | c.1882C>A p.R628= | Silent (SNP) | VAF 64/193 reads (33%) | catalogued as COSV99031691; called by muse, mutect2, varscan2
- FGF23 | c.330G>A p.P110= | Silent (SNP) | VAF 201/597 reads (34%) | catalogued as rs1202091925, COSV52976226; called by muse, mutect2, varscan2
- HAUS8 | c.45C>T p.G15= | Silent (SNP) | VAF 35/339 reads (10%) | called by muse, mutect2
- JPH2 | c.1461G>A p.P487= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs781613132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMNA | c.480C>T p.G160= | Silent (SNP) | VAF 85/276 reads (31%) | catalogued as rs758848135, COSV100738628; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP1B | c.6753A>C p.I2251= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV67183150; called by muse, mutect2
- MAB21L1 | c.171C>T p.N57= | Silent (SNP) | VAF 38/285 reads (13%) | called by muse, mutect2, varscan2
- OR11H4 | c.663T>C p.S221= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs1233187092; called by muse, mutect2, varscan2
- OR2J3 | c.720G>A p.V240= | Silent (SNP) | VAF 35/152 reads (23%) | called by muse, mutect2, varscan2
- OR5D18 | c.660G>A p.A220= | Silent (SNP) | VAF 33/295 reads (11%) | catalogued as rs779827741, COSV61737938, COSV61738052; called by muse, mutect2, varscan2
- PTPRJ | c.1701C>T p.S567= | Silent (SNP) | VAF 51/315 reads (16%) | catalogued as rs142074473; called by muse, mutect2, varscan2
- RGS7BP | c.138C>T p.T46= | Silent (SNP) | VAF 37/156 reads (24%) | called by muse, mutect2
- TBCB | c.429C>T p.A143= | Silent (SNP) | VAF 92/356 reads (26%) | called by muse, mutect2, varscan2
- BPTF | c.8640-747G>A | Intron (SNP) | VAF 30/117 reads (26%) | called by muse, mutect2, varscan2
- C3orf35 | chr3:37417698 G>A | 3'Flank (SNP) | VAF 16/89 reads (18%) | catalogued as rs554690420; called by muse, mutect2, varscan2
- DDX31 | c.2141-17G>A | Intron (SNP) | VAF 102/318 reads (32%) | catalogued as rs572017150; called by muse, mutect2, varscan2
- DUOX2 | c.715+16C>T | Intron (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- FYN | c.862+533G>A | Intron (SNP) | VAF 36/106 reads (34%) | catalogued as rs777800541; called by muse, mutect2, varscan2
- PCLO | c.14791+9C>T | Intron (SNP) | VAF 126/312 reads (40%) | catalogued as COSV61616495; called by muse, mutect2, varscan2
- PGLYRP2 | c.1641+43G>A | Intron (SNP) | VAF 21/78 reads (27%) | catalogued as COSV52990929; called by muse, mutect2, varscan2
- RGP1 | c.-107C>A | 5'UTR (SNP) | VAF 70/320 reads (22%) | called by muse, varscan2
- STXBP2 | c.578+26C>T | Intron (SNP) | VAF 51/164 reads (31%) | catalogued as rs747100746; called by muse, mutect2, varscan2
